Somatic mutation profile of tumor specimen ALCH-B4XN-TTP1-A (aliquot ALCH-B4XN-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4XN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.4 years (24,992 days).
Specimen ALCH-B4XN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 794efbb5-dfb5-4931-b3d2-31525596a34c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4XN-NB1-A (Blood Derived Normal), aliquot ALCH-B4XN-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/880e4e67-d19d-4493-8b68-cf76af21fe93

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Intron 3, Nonsense Mutation 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 90/604 reads (15%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel
- TP53 | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 56/394 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>G p.R502G | Missense Mutation (SNP) | VAF 224/498 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs200627716; called by muse, mutect2, varscan2
- BRWD1 | c.6920T>C p.L2307P | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs763436014, COSV58999873; called by muse, mutect2, varscan2
- C20orf144 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 43/372 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs768782763, COSV99865217; called by muse, mutect2, varscan2
- CBX7 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1258535046; called by muse, mutect2, varscan2
- DCLRE1C | c.1078C>T p.R360W (on ENST00000378278 / NM_001350965.2; = p.R245W on NM_022487.4) | Missense Mutation (SNP) | VAF 34/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748164114; ClinVar: uncertain significance; called by muse, mutect2
- ELFN1 | c.1969G>A p.V657I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1206191418; called by muse, mutect2, varscan2
- GRM1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.591); catalogued as rs760713702, COSV51377621, COSV99265501; called by muse, varscan2
- NOTCH4 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 20/646 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66683226; called by muse, mutect2
- R3HDML | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1459496658; called by muse, mutect2
- RNF152 | c.288C>A p.S96R | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as COSV57184555; called by muse, mutect2
- UVSSA | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376949347; called by muse, mutect2
- ZFP1 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs35073382; called by muse, mutect2, varscan2
- ANO5 | c.1102A>C p.T368P | Missense Mutation (SNP) | VAF 29/451 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- BRCA1 | c.2303G>A p.S768N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CUBN | c.2228G>A p.G743E | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DRD5 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- INTS6 | c.2396T>C p.L799S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, varscan2
- NCAPG2 | c.151T>A p.W51R | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NMRAL1 | c.763C>G p.R255G | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NTRK3 | c.1595A>G p.H532R | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- OR4C11 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- PAK5 | c.1688G>C p.G563A | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLEC | c.11387C>G p.S3796C (on ENST00000322810 / NM_201380.4; = p.S3686C on NM_000445.5) | Missense Mutation (SNP) | VAF 166/549 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- TNR | c.3242G>A p.S1081N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.688); called by muse, mutect2
- CCDC3 | c.765G>A p.P255= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs374950220; called by muse, mutect2, varscan2
- DYNC2H1 | c.4770C>T p.G1590= | Silent (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- FLG | c.11067G>A p.Q3689= | Silent (SNP) | VAF 34/770 reads (4%) | called by muse, mutect2
- FLNC | c.240G>A p.K80= | Silent (SNP) | VAF 37/313 reads (12%) | called by muse, mutect2, varscan2
- PADI1 | c.1254C>T p.V418= | Silent (SNP) | VAF 11/222 reads (5%) | called by muse, mutect2
- POU4F3 | c.594C>T p.R198= | Silent (SNP) | VAF 20/245 reads (8%) | called by muse, mutect2
- RAB11FIP3 | c.1623C>T p.I541= | Silent (SNP) | VAF 16/178 reads (9%) | catalogued as rs143343068; called by muse, mutect2
- DEFB119 | c.61+1256G>A | Intron (SNP) | VAF 53/349 reads (15%) | catalogued as rs762049328, COSV59266391; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2432G>T | Intron (SNP) | VAF 24/489 reads (5%) | called by muse, mutect2
- PTPRT | c.2983-736G>A | Intron (SNP) | VAF 21/237 reads (9%) | catalogued as rs538761055; called by muse, mutect2
- RAB5B | c.*335T>G | 3'UTR (SNP) | VAF 27/246 reads (11%) | called by muse, mutect2, varscan2
